Somatic mutation profile of tumor specimen TARGET-30-PAPEFE-01A (aliquot TARGET-30-PAPEFE-01A-01W) from TARGET case TARGET-30-PAPEFE, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.7 years (990 days).
Specimen TARGET-30-PAPEFE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de010366-04fc-4834-a1bc-df24c8443f5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPEFE-10A (Blood Derived Normal), aliquot TARGET-30-PAPEFE-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ae40673-7056-4168-a55d-6537b1aa4ded

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A1 | c.696+1G>T p.X232_splice | Splice Site (SNP) | VAF 10/229 reads (4%) | catalogued as CS157539; called by muse, mutect2
- IGBP1P2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.049); catalogued as COSV53614401; called by muse, mutect2, varscan2
- MYLK | c.3295G>A p.A1099T | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs777804948; called by muse, mutect2
- PCDH9 | c.3221T>A p.V1074E (on ENST00000377865 / NM_203487.3; = p.V1040E on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.221); catalogued as COSV60541128; called by muse, mutect2, varscan2
- THBS1 | c.3124C>A p.Q1042K | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); catalogued as COSV52951315; called by muse, mutect2
- TPH2 | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.698); catalogued as COSV61591425; called by mutect2, varscan2
- TRAFD1 | c.1666G>T p.A556S | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.23); catalogued as COSV57503224, COSV57504058; called by muse, mutect2, varscan2
- IFIH1 | c.1008C>A p.T336= | Silent (SNP) | VAF 24/563 reads (4%) | catalogued as COSV99718710; called by muse, mutect2
